Somatic mutation profile of tumor specimen MMRF_1912_3_PB_CD138pos (aliquot MMRF_1912_3_PB_CD138pos_T1_KHS5U_K15172) from MMRF case MMRF_1912, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.0 years (21,197 days).
Specimen MMRF_1912_3_PB_CD138pos: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39d1ee65-4150-41c9-843d-bcdab475321a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1912_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1912_1_PB_CD3pos_C4_KBS5U_L05817; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12a124cf-19bf-47a9-a2b6-45cd46f97813

The open-access MAF lists 737 somatic variants for this specimen: 233 protein-altering or splice-affecting, 86 silent, 418 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 214, Missense Mutation 201, Intron 105, Silent 86, 5'UTR 50, 5'Flank 24, Nonsense Mutation 14, 3'Flank 13, RNA 12, Splice Site 6, Splice Region 5, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC138647.1 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1449409223; called by muse, mutect2, varscan2
- ADAMTS2 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51083793; called by muse, mutect2, varscan2
- ADGRV1 | c.14852C>T p.S4951F | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1187404598; called by muse, mutect2, varscan2
- ASIC2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs749146881, COSV63293686; called by muse, mutect2, varscan2
- BICD1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.112); catalogued as rs1176204686; called by muse, mutect2, varscan2
- C1orf167 | c.2155G>C p.E719Q | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (1); catalogued as rs1385146359; called by muse, mutect2, varscan2
- C2orf91 | n.473C>G | Splice Region (SNP) | VAF 77/218 reads (35%) | catalogued as COSV101106428; called by muse, mutect2, varscan2
- CDK5RAP2 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV62572368; called by muse, mutect2, varscan2
- CGAS | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779830325; called by muse, mutect2
- CRYBG2 | c.4019C>T p.S1340L | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57487903; called by muse, mutect2, varscan2
- CYLD | c.2042-1G>T p.X681_splice | Splice Site (SNP) | VAF 16/40 reads (40%) | catalogued as CS154513; called by muse, mutect2, varscan2
- DENND1C | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 93/196 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV57568717; called by muse, mutect2, varscan2
- DHX29 | c.3920G>A p.R1307Q | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.097); catalogued as rs752824993; called by muse, mutect2, varscan2
- DOK3 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as rs748836235; called by muse, mutect2, varscan2
- DPYSL3 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs751361322, COSV58330391; called by muse, mutect2, varscan2
- EPHA8 | c.2330C>G p.S777C | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1165586714; called by muse, mutect2, varscan2
- ETS1 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.129); catalogued as COSV101200344; called by muse, mutect2, varscan2
- FBXO41 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV54586684; called by muse, mutect2, varscan2
- FIGN | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs576789489, COSV100291917, COSV60764866; called by muse, mutect2, varscan2
- FNDC3B | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0.048); catalogued as rs993970476; called by muse, mutect2, varscan2
- FRMD1 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.776); catalogued as rs752860506; called by muse, mutect2, varscan2
- GALNTL5 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as rs368842809, COSV67180145; called by muse, mutect2, varscan2
- GNG8 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.059); catalogued as rs532299872; called by muse, mutect2, varscan2
- GRIA2 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 142/403 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52390630; called by muse, mutect2, varscan2
- GSTO1 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV63846561; called by muse, mutect2, varscan2
- HEPHL1 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as rs1330956914; called by muse, mutect2, varscan2
- HOMEZ | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV62537253; called by muse, mutect2, varscan2
- HYDIN | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.04); catalogued as rs372727845; called by muse, mutect2, varscan2
- INPPL1 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53354342; called by muse, mutect2, varscan2
- INTS9 | c.1056G>C p.Q352H | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs755712559; called by muse, mutect2, varscan2
- IRX2 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.32); catalogued as COSV57409611, COSV57413864; called by muse, mutect2, varscan2
- JPT2 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1030958285, COSV50188487, COSV99027989; called by muse, mutect2, varscan2
- KIF14 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV66264016; called by muse, mutect2, varscan2
- KIF22 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs773857563; called by mutect2, varscan2
- KLC3 | c.-8-6C>T | Splice Region (SNP) | VAF 43/130 reads (33%) | catalogued as rs1276709925; called by muse, mutect2, varscan2
- LIN54 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs776973799; called by muse, mutect2, varscan2
- LRRC47 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as rs760459981, COSV65562164, COSV65562861; called by muse, mutect2, varscan2
- MAK | c.1304A>T p.D435V | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV57564560; called by muse, mutect2, varscan2
- MICALL2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1460001126; called by muse, mutect2, varscan2
- MROH7 | c.1365G>C p.K455N | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV59877847; called by mutect2, varscan2
- MRPL54 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs779084462; called by muse, mutect2, varscan2
- MYH13 | c.5117C>G p.S1706* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as rs760378346; called by muse, mutect2, varscan2
- NAT10 | c.1070G>C p.R357T | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1045755124; called by muse, varscan2
- NDC80 | c.4A>C p.K2Q | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as COSV99859329; called by muse, mutect2
- NMU | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV51702616; called by muse, mutect2, varscan2
- PBX2 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as COSV66708712; called by muse, mutect2, varscan2
- PKHD1L1 | c.5986G>C p.E1996Q | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV99058815; called by muse, mutect2, varscan2
- PTDSS2 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57278153; called by muse, mutect2, varscan2
- PTPN6 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV59684388; called by muse, mutect2, varscan2
- RFWD3 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1184458444, COSV63098989; called by muse, mutect2, varscan2
- RPL8 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs777113990; called by muse, mutect2, varscan2
- SACS | c.6577G>A p.D2193N | Missense Mutation (SNP) | VAF 68/115 reads (59%) | SIFT tolerated (0.41); PolyPhen benign (0.137); catalogued as rs149278134; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCAP | c.2515G>C p.D839H | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.359); catalogued as rs1341551376; called by muse, mutect2, varscan2
- SCN9A | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.284); catalogued as COSV57606941; called by muse, mutect2, varscan2
- SEBOX | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV52647636; called by muse, mutect2, varscan2
- SETD2 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.469); catalogued as COSV57437148, COSV57449212; called by muse, mutect2, varscan2
- SH3PXD2A | c.328dup p.H110Pfs*6 | Frame Shift Ins (INS) | VAF 46/126 reads (37%) | catalogued as rs777796332; called by mutect2, varscan2
- SKAP2 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV104422320; called by muse, mutect2, varscan2
- SLC25A20 | c.291G>C p.K97N | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59804496, COSV59804591; called by muse, mutect2, varscan2
- SLC2A13 | c.1368G>C p.K456N | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99786345; called by muse, mutect2, varscan2
- SLC38A1 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV67063966; called by muse, mutect2, varscan2
- SP140 | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs1304344903; called by muse, mutect2, varscan2
- SPHKAP | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747553444, COSV60874023; called by muse, mutect2, varscan2
- TCHHL1 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs771462113; called by muse, varscan2
- TENM2 | c.2380G>A p.E794K (on ENST00000518659 / NM_001122679.2; = p.E562K on NM_001080428.3) | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.744); catalogued as rs1259911343; called by muse, mutect2, varscan2
- TRPC4AP | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV99327965; called by muse, mutect2, varscan2
- TRPV3 | c.669C>G p.I223M | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1404147400; called by muse, mutect2, varscan2
- TTC36 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100244666; called by muse, mutect2, varscan2
- UCKL1 | c.657C>T p.L219= | Splice Region (SNP) | VAF 37/122 reads (30%) | catalogued as rs1281917749; called by muse, mutect2, varscan2
- USP49 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs548556992, COSV51897822; called by muse, mutect2, varscan2
- WDR47 | c.1326G>T p.Q442H (on ENST00000369962 / NM_001142551.2; = p.Q443H on NM_014969.5) | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100728251; called by muse, mutect2, varscan2
- WDR97 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1250878822; called by muse, mutect2, varscan2
- XYLT1 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV54475980, COSV54477959; called by muse, mutect2, varscan2
- ZGRF1 | c.2564G>A p.G855E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs896620823, COSV100005802; called by muse, mutect2, varscan2
- ZNF281 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs747158613; called by muse, mutect2, varscan2
- ZNF496 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.188); catalogued as rs575003355; called by muse, mutect2, varscan2
- ZNF654 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58851997; called by muse, varscan2
- ZSWIM5 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1239778288; called by muse, mutect2, varscan2
- ADCK2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- AL441992.2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANGPT1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK3 | c.8704G>A p.E2902K | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ANK3 | c.4294T>A p.L1432I (on ENST00000280772 / NM_001320874.2; = p.L566I on NM_001149.3) | Missense Mutation (SNP) | VAF 10/259 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ARPC2 | c.563G>C p.G188A | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.066); called by muse, mutect2
- ARPP21 | c.687-1G>T p.X229_splice | Splice Site (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- ARSJ | c.1412C>G p.S471C | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ATAD1 | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ATG4B | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATL2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); called by muse, varscan2
- ATN1 | c.3262C>T p.H1088Y | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ATP6V0A1 | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- B4GALT2 | c.752C>G p.A251G | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- BBOX1 | c.917G>C p.R306T | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- BPI | c.869C>T p.S290L (on ENST00000262865; = p.S286L on NM_001725.3) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- BPTF | c.8505G>C p.Q2835H | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BYSL | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CACNA1B | c.6319G>C p.E2107Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2
- CACNA1D | c.3266C>G p.S1089C (on ENST00000350061 / NM_001128840.3; = p.S1109C on NM_000720.4) | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CARF | c.1379G>C p.R460T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC3 | c.729G>C p.Q243H | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD5 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CDKN1C | c.794A>G p.K265R | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- CDKN1C | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPU | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CEP97 | c.1202C>T p.S401L | Missense Mutation (SNP) | VAF 96/282 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, varscan2
- CFAP44 | c.1143C>G p.I381M | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- CFAP92 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- CFP | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 63/75 reads (84%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CHD7 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CLEC16A | c.2845C>A p.P949T | Missense Mutation (SNP) | VAF 120/307 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CLUAP1 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRLF3 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.034); called by muse, mutect2
- DCAF13 | c.1025G>A p.C342Y | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- DCAF8L2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 49/67 reads (73%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- DHX37 | c.2835G>C p.E945D | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DNAH14 | c.2796G>C p.L932F (on ENST00000445597; = p.L998F on NM_001367479.1) | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- DOCK10 | c.1298G>A p.R433K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DST | c.11732C>T p.S3911L (on ENST00000361203 / NM_001374722.1; = p.S1499L on NM_015548.5) | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DTWD2 | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EBNA1BP2 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EME2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EPB41L5 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- EPG5 | c.3532C>T p.Q1178* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- EPN2 | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | called by muse, varscan2
- FAM117A | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- FAM171A2 | c.2208G>T p.E736D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- FASTKD2 | c.1575C>G p.I525M | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FAT3 | c.11857G>A p.E3953K | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FBN2 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FIBP | c.700G>C p.D234H (on ENST00000338369 / NM_198897.2; = p.D227H on NM_004214.5) | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FMO2 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- FREM2 | c.5642-1G>C p.X1881_splice | Splice Site (SNP) | VAF 20/32 reads (63%) | called by muse, mutect2, varscan2
- FTL | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- FZD10 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- GMCL1 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 33/102 reads (32%) | called by muse, mutect2, varscan2
- GOLGA2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GRK4 | c.1411C>T p.H471Y (on ENST00000398052 / NM_182982.3; = p.H439Y on NM_005307.3) | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- HAUS5 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- HCFC2 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.186); called by muse, mutect2
- IGF2BP2 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 92/237 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- IGHV2-70D | c.337A>T p.T113S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, varscan2
- IGHV2-70D | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, varscan2
- IGLV3-10 | c.47-2A>T p.X16_splice | Splice Site (SNP) | VAF 45/69 reads (65%) | called by muse, mutect2, varscan2
- IMMP1L | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- INTS1 | c.5566G>T p.E1856* | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- IRF1 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- ITGA8 | c.66C>A p.C22* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | called by muse, varscan2
- ITGAM | c.2169C>G p.I723M (on ENST00000648685 / NM_001145808.2; = p.I722M on NM_000632.4) | Missense Mutation (SNP) | VAF 88/251 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ITGAV | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KDELR3 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- KDM4A | c.2584C>T p.Q862* | Nonsense Mutation (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- KIAA0232 | c.437-1G>A p.X146_splice | Splice Site (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2
- KIF21A | c.2621C>G p.S874* (on ENST00000361418 / NM_001378440.1; = p.S861* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- KLF13 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LCTL | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/93 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- LINC00583 | n.171C>T | Splice Region (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- LSM11 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- METTL3 | c.202_218del p.A68Yfs*4 | Frame Shift Del (DEL) | VAF 40/144 reads (28%) | called by mutect2, varscan2
- MMS22L | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- MPDZ | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 54/129 reads (42%) | called by muse, mutect2, varscan2
- MROH2B | c.2869C>G p.L957V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MST1 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- MTCL1 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- MYH15 | c.4363G>T p.D1455Y | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- MYO10 | c.4750G>A p.D1584N | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); called by muse, varscan2
- MYO16 | c.4834G>A p.E1612K | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYOM3 | c.2155G>C p.G719R | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBEAL2 | c.7189C>T p.H2397Y | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- NEDD1 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- NES | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- OPN3 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAXIP1 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIK3C2B | c.3925G>C p.E1309Q | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- PLCE1 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLEKHG4 | c.1666G>C p.E556Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PM20D2 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- PPARG | c.804G>C p.K268N (on ENST00000287820 / NM_015869.5; = p.K238N on NM_005037.7) | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PPFIA3 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PRKG1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRORP | c.1100G>T p.C367F | Missense Mutation (SNP) | VAF 19/512 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- PRSS2 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PUS1 | c.304-4C>A | Splice Region (SNP) | VAF 38/103 reads (37%) | called by muse, mutect2, varscan2
- RCC2 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RIC8B | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ROBO3 | c.2226C>G p.I742M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- ROS1 | c.5486G>C p.R1829T | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SACS | c.3411G>C p.K1137N | Missense Mutation (SNP) | VAF 87/131 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SALL1 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- SALL3 | c.2562G>A p.M854I | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SCARF2 | c.2527del p.R843Gfs*101 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | called by mutect2, varscan2
- SCN9A | c.5803G>A p.D1935N (on ENST00000303354; = p.D1924N on NM_002977.3) | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SFPQ | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SGMS1 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SHOC1 | c.3973C>T p.Q1325* | Nonsense Mutation (SNP) | VAF 95/242 reads (39%) | called by muse, mutect2, varscan2
- SLC22A11 | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SLC2A11 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 82/250 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC47A1 | c.1287dup p.A430Cfs*70 | Frame Shift Ins (INS) | VAF 23/86 reads (27%) | called by pindel, varscan2
- SLC8A1 | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA5 | c.2878C>T p.H960Y | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SMG1 | c.4738G>A p.E1580K | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0.017); called by muse, mutect2
- SNX17 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SOS2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SPOPL | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- SPTA1 | c.4657G>A p.E1553K | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- SQLE | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- SRGAP1 | c.1625G>C p.R542T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCHHL1 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TLN1 | c.4812G>C p.K1604N | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- TMED8 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TMEM132C | c.707A>T p.N236I | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.195); called by muse, mutect2
- TPBGL | c.1130C>A p.S377Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- TRAF6 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- TRAPPC4 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRAPPC4 | c.558C>G p.F186L | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM25 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TRIM33 | c.2997A>T p.K999N | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- TRPC3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTK | c.1990G>T p.D664Y | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UMODL1 | c.2834C>T p.S945F (on ENST00000408910 / NM_001004416.2; = p.S1073F on NM_173568.3) | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- UNC5B | c.16G>T p.G6* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2, varscan2
- VPS13D | c.12656_12658del p.G4219_P4220delinsA | In Frame Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- VWA5B2 | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.94); called by muse, varscan2
- WEE1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 20/427 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- XPA | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YWHAB | c.237G>C p.Q79H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZBTB47 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZC3H7B | c.2518-1G>C p.X840_splice | Splice Site (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- ZC3H8 | c.522G>C p.E174D | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ZNF131 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF354B | c.1431G>C p.Q477H | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ZNF571 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZNF747 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- ZXDA | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- AKT1S1 | c.654C>T p.I218= (on ENST00000344175 / NM_001098633.4; = p.I238= on NM_032375.5) | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs766848323, COSV59273976; called by muse, mutect2, varscan2
- ANKMY1 | c.348C>T p.L116= | Silent (SNP) | VAF 36/95 reads (38%) | called by muse, mutect2, varscan2
- ARL16 | c.411C>G p.L137= | Silent (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- AUTS2 | c.2205C>T p.L735= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as rs1301078103; called by muse, mutect2, varscan2
- B4GALNT3 | c.60G>A p.R20= | Silent (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- BBC3 | c.390C>T p.L130= (on ENST00000449228 / NM_001127240.3; = p.S96L on NM_014417.5) | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs747413729; called by muse, mutect2, varscan2
- BHMT2 | c.129C>G p.L43= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV54873810; called by muse, mutect2
- BTBD9 | c.1554C>T p.V518= | Silent (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- C12orf57 | c.180G>A p.Q60= | Silent (SNP) | VAF 41/124 reads (33%) | called by muse, mutect2, varscan2
- CACNG6 | c.195C>T p.L65= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as rs769787760; called by muse, mutect2, varscan2
- CENPF | c.1143C>T p.A381= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs1173255326; called by mutect2, varscan2
- CLDN3 | c.534G>A p.A178= | Silent (SNP) | VAF 46/100 reads (46%) | called by muse, varscan2
- CLTB | c.132C>T p.F44= | Silent (SNP) | VAF 70/171 reads (41%) | called by muse, mutect2, varscan2
- CNBD1 | c.471G>A p.L157= | Silent (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- CYP27C1 | c.255C>T p.I85= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as rs146690447; called by muse, mutect2, varscan2
- DAGLB | c.1461C>T p.I487= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs758391168; called by muse, mutect2, varscan2
- DBR1 | c.441C>T p.I147= | Silent (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- DDX23 | c.1689C>T p.V563= | Silent (SNP) | VAF 55/142 reads (39%) | called by muse, mutect2, varscan2
- DDX24 | c.2553G>A p.Q851= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- DENND5A | c.744C>G p.L248= | Silent (SNP) | VAF 59/146 reads (40%) | called by muse, mutect2, varscan2
- DNAH10 | c.6117C>G p.A2039= (on ENST00000409039; = p.A1978= on NM_207437.3) | Silent (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- DNAH3 | c.1887G>A p.L629= | Silent (SNP) | VAF 58/163 reads (36%) | catalogued as rs148819655; called by muse, mutect2, varscan2
- EPG5 | c.4173G>A p.L1391= | Silent (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- FBXO39 | c.483C>T p.G161= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs377688513; called by muse, mutect2, varscan2
- GLYCTK | c.1206C>T p.V402= | Silent (SNP) | VAF 49/126 reads (39%) | called by muse, mutect2, varscan2
- GPAT2 | c.1296C>G p.L432= | Silent (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- GRIN2B | c.1275G>A p.L425= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs950679024; ClinVar: likely benign; called by muse, mutect2, varscan2
- HEXD | c.1116C>T p.V372= (on ENST00000327949 / NM_001369487.1; = p.S402L on NM_173620.3) | Silent (SNP) | VAF 52/127 reads (41%) | catalogued as COSV60063630; called by muse, mutect2, varscan2
- HS1BP3 | c.243G>C p.L81= | Silent (SNP) | VAF 53/190 reads (28%) | called by muse, mutect2, varscan2
- IL6R | c.381C>T p.L127= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV59820004; called by muse, mutect2, varscan2
- INPP5B | c.2937G>A p.K979= (on ENST00000373023; = p.K899= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 78/198 reads (39%) | called by muse, mutect2, varscan2
- KCNJ14 | c.30C>T p.L10= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs928639669, COSV53519720; called by muse, mutect2, varscan2
- KDSR | c.702G>A p.E234= | Silent (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- KLHL6 | c.141C>T p.V47= | Silent (SNP) | VAF 88/225 reads (39%) | catalogued as rs1004787604, COSV58069925; called by muse, varscan2
- LCT | c.5580C>T p.I1860= | Silent (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- MED25 | c.1977G>T p.G659= | Silent (SNP) | VAF 17/38 reads (45%) | called by muse, varscan2
- MKRN1 | c.1005G>A p.R335= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as rs1062773; called by muse, mutect2, varscan2
- MUC4 | c.13353C>T p.V4451= (on ENST00000463781 / NM_018406.7; = p.V215= on NM_004532.6) | Silent (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- NAGK | c.78C>T p.I26= | Silent (SNP) | VAF 64/159 reads (40%) | called by muse, mutect2, varscan2
- NDST4 | c.1105C>A p.R369= | Silent (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- NDUFA7 | c.21C>G p.L7= | Silent (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- NELFCD | c.1485G>A p.V495= (on ENST00000602795; = p.V477= on NM_198976.4) | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as rs376830862; called by muse, mutect2, varscan2
- NGEF | c.1893G>A p.L631= | Silent (SNP) | VAF 51/144 reads (35%) | catalogued as rs142650451; called by muse, mutect2, varscan2
- NLGN2 | c.1695C>T p.F565= | Silent (SNP) | VAF 59/122 reads (48%) | catalogued as rs751321187; called by muse, mutect2, varscan2
- NOL11 | c.456G>C p.V152= | Silent (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- NOX5 | c.1689C>A p.I563= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV99534541; called by muse, mutect2, varscan2
- NOXRED1 | c.786G>A p.L262= | Silent (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- NSUN7 | c.1467C>T p.F489= | Silent (SNP) | VAF 33/96 reads (34%) | called by muse, mutect2, varscan2
- OSBPL2 | c.318G>A p.R106= (on ENST00000313733 / NM_144498.4; = p.R94= on NM_014835.4) | Silent (SNP) | VAF 22/328 reads (7%) | catalogued as COSV100569120; called by muse, mutect2
- PCDHGB2 | c.1536G>T p.G512= | Silent (SNP) | VAF 55/111 reads (50%) | catalogued as rs929366639; called by muse, mutect2, varscan2
- PDIA3 | c.21G>A p.A7= | Silent (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- PLCD3 | c.903C>G p.L301= | Silent (SNP) | VAF 12/54 reads (22%) | called by mutect2, varscan2
- PURG | c.393G>C p.L131= | Silent (SNP) | VAF 54/142 reads (38%) | catalogued as COSV53295591, COSV53296220; called by muse, mutect2, varscan2
- RAI1 | c.5334G>C p.R1778= | Silent (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- RARS1 | c.66G>A p.L22= | Silent (SNP) | VAF 52/107 reads (49%) | called by muse, mutect2, varscan2
- RARS1 | c.1890G>A p.V630= | Silent (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
- RETREG3 | c.225G>A p.L75= | Silent (SNP) | VAF 68/155 reads (44%) | catalogued as COSV52220680; called by muse, varscan2
- RNF186 | c.159C>G p.P53= | Silent (SNP) | VAF 44/131 reads (34%) | called by muse, mutect2, varscan2
- RSF1 | c.3294C>T p.S1098= | Silent (SNP) | VAF 8/199 reads (4%) | called by muse, mutect2
- SBF1 | c.2091C>G p.L697= | Silent (SNP) | VAF 26/72 reads (36%) | called by muse, varscan2
- SCRT2 | c.426G>A p.A142= | Silent (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- SDF4 | c.522C>T p.I174= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as COSV55420785, COSV99027809; called by muse, mutect2, varscan2
- SLC35F3 | c.87G>A p.R29= | Silent (SNP) | VAF 64/193 reads (33%) | catalogued as rs750181555, COSV64027973; called by muse, mutect2, varscan2
- SLC9A9 | c.264C>T p.F88= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV57230334; called by muse, mutect2, varscan2
- SPCS2 | c.522G>C p.L174= | Silent (SNP) | VAF 86/243 reads (35%) | called by muse, mutect2, varscan2
- SPIN1 | c.732C>T p.F244= | Silent (SNP) | VAF 50/153 reads (33%) | catalogued as rs1424727512; called by muse, mutect2, varscan2
- SSC4D | c.861C>G p.L287= | Silent (SNP) | VAF 14/45 reads (31%) | called by mutect2, varscan2
- SYNE1 | c.21540G>A p.L7180= (on ENST00000367255 / NM_182961.4; = p.L7109= on NM_033071.3) | Silent (SNP) | VAF 71/191 reads (37%) | called by muse, mutect2, varscan2
- TBC1D8 | c.646C>T p.L216= | Silent (SNP) | VAF 54/150 reads (36%) | catalogued as rs1474291960; called by muse, varscan2
- TBC1D9 | c.3759C>T p.L1253= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV71307368; called by muse, mutect2, varscan2
- TGFB2 | c.246G>A p.A82= | Silent (SNP) | VAF 37/160 reads (23%) | called by muse, mutect2, varscan2
- THSD7B | c.2109C>G p.V703= | Silent (SNP) | VAF 42/117 reads (36%) | called by muse, mutect2, varscan2
- TMC7 | c.2046C>T p.F682= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs1195732483, COSV58581655; called by muse, mutect2, varscan2
- TMED9 | c.27C>T p.L9= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs759506866; called by muse, mutect2
- TNPO1 | c.2421C>T p.T807= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- TPSB2 | c.210G>A p.L70= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs775320822; called by muse, mutect2, varscan2
- TRPC7 | c.118C>T p.L40= | Silent (SNP) | VAF 70/204 reads (34%) | called by mutect2, varscan2
- TRPV1 | c.1470C>T p.F490= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs1482230799; called by muse, mutect2, varscan2
- TRRAP | c.5898G>A p.L1966= (on ENST00000359863 / NM_001244580.1; = p.L1948= on NM_003496.3) | Silent (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- UBE2Z | c.612G>A p.Q204= | Silent (SNP) | VAF 48/109 reads (44%) | catalogued as COSV100711560; called by muse, mutect2, varscan2
- USP53 | c.1266C>T p.H422= | Silent (SNP) | VAF 46/118 reads (39%) | called by muse, mutect2, varscan2
- VPS13A | c.3792G>A p.L1264= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs1247441048, COSV62437475; called by muse, mutect2, varscan2
- XPR1 | c.1539G>A p.L513= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as rs750004423, COSV62558470; called by muse, mutect2, varscan2
- ZDHHC16 | c.15G>A p.R5= | Silent (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- ZNF365 | c.984G>C p.S328= | Silent (SNP) | VAF 78/206 reads (38%) | catalogued as COSV67926701; called by muse, mutect2, varscan2
- ZNF691 | c.282C>G p.V94= (on ENST00000372502; = p.V63= on NM_015911.3) | Silent (SNP) | VAF 44/123 reads (36%) | catalogued as COSV65289738; called by muse, mutect2, varscan2
- ABHD6 | c.119+1790C>G | Intron (SNP) | VAF 85/235 reads (36%) | called by muse, mutect2, varscan2
- ABLIM1 | chr10:114431406 G>A | 3'Flank (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- ABRACL | c.61+286T>C | Intron (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- AC009779.3 | c.*1177C>T | 3'UTR (SNP) | VAF 49/116 reads (42%) | called by muse, mutect2, varscan2
- AC011525.1 | n.1505G>T | RNA (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- AC073578.1 | n.921C>T | RNA (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- AC074085.2 | n.59G>A | RNA (SNP) | VAF 47/176 reads (27%) | catalogued as rs1239477899; called by muse, mutect2, varscan2
- AC115837.1 | n.222-337C>T | Intron (SNP) | VAF 17/404 reads (4%) | called by muse, mutect2
- ACTL10 | c.-794G>A | 5'UTR (SNP) | VAF 69/162 reads (43%) | called by muse, mutect2, varscan2
- ADAM9 | chr8:38996951 C>T | 5'Flank (SNP) | VAF 25/58 reads (43%) | catalogued as rs1004167249; called by muse, mutect2
- ADAM9 | c.2210+67C>T | Intron (SNP) | VAF 12/24 reads (50%) | catalogued as rs1196392530; called by muse, mutect2
- ADAMTS13 | c.-19C>T | 5'UTR (SNP) | VAF 36/83 reads (43%) | catalogued as rs782227169, COSV100746907; called by muse, mutect2, varscan2
- ADAR | c.2497-73C>T | Intron (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.-90C>T | 5'UTR (SNP) | VAF 36/108 reads (33%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.*2878C>G | 3'UTR (SNP) | VAF 54/133 reads (41%) | called by muse, mutect2
- ADD1 | c.1161+129G>A | Intron (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- ADD3 | c.*1684G>C | 3'UTR (SNP) | VAF 14/50 reads (28%) | called by mutect2, varscan2
- ADGRE3 | c.*106G>C | 3'UTR (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- ADTRP | c.*821G>A | 3'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- AGPAT2 | c.*598C>G | 3'UTR (SNP) | VAF 59/137 reads (43%) | called by muse, mutect2, varscan2
- AIF1L | c.*1955G>A | 3'UTR (SNP) | VAF 75/194 reads (39%) | called by muse, mutect2, varscan2
- AKAP10 | c.-94C>T | 5'UTR (SNP) | VAF 28/65 reads (43%) | catalogued as rs1436252948; called by muse, mutect2, varscan2
- AL162417.1 | c.397-17010C>G | Intron (SNP) | VAF 31/82 reads (38%) | catalogued as COSV64454486; called by muse, mutect2, varscan2
- ALDH1A3 | c.*1530G>C | 3'UTR (SNP) | VAF 42/106 reads (40%) | called by muse, mutect2, varscan2
- AMDHD1 | c.*419T>G | 3'UTR (SNP) | VAF 28/74 reads (38%) | catalogued as rs551075382; called by muse, varscan2
- ANK1 | c.126+67754G>A | Intron (SNP) | VAF 41/107 reads (38%) | called by muse, mutect2, varscan2
- ANKDD1A | c.*295C>G | 3'UTR (SNP) | VAF 22/95 reads (23%) | catalogued as rs761577177; called by muse, mutect2, varscan2
- ANKRD29 | c.*1950G>C | 3'UTR (SNP) | VAF 46/118 reads (39%) | called by muse, mutect2, varscan2
- AP3S2 | chr15:89894333 C>T | 5'Flank (SNP) | VAF 54/145 reads (37%) | called by muse, mutect2, varscan2
- APPL2 | chr12:105236350 G>A | 5'Flank (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2
- ARHGAP26 | c.-334G>A | 5'UTR (SNP) | VAF 22/72 reads (31%) | catalogued as rs1466535811; called by muse, mutect2, varscan2
- ARHGAP5 | c.*3952C>G | 3'UTR (SNP) | VAF 36/92 reads (39%) | called by muse, mutect2, varscan2
- ARID2 | chr12:45727455 G>A | 5'Flank (SNP) | VAF 46/136 reads (34%) | called by muse, mutect2, varscan2
- ARIH2 | c.-97-42C>T | Intron (SNP) | VAF 31/70 reads (44%) | catalogued as COSV62705975; called by muse, mutect2, varscan2
- ARSJ | c.*1819G>A | 3'UTR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- ASCC1 | c.*531C>G | 3'UTR (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- ASCC3 | c.241+6224G>C | Intron (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- ATF5 | c.*86C>T | 3'UTR (SNP) | VAF 7/19 reads (37%) | catalogued as rs757195194; called by muse, varscan2
- BACE1 | c.*3738G>T | 3'UTR (SNP) | VAF 56/162 reads (35%) | called by muse, mutect2, varscan2
- BAIAP2 | c.280-115C>T | Intron (SNP) | VAF 81/191 reads (42%) | called by muse, mutect2, varscan2
- BARX1 | c.*379C>T | 3'UTR (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- BBC3 | c.378-253C>T | Intron (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
- BDNF | c.*2187G>C | 3'UTR (SNP) | VAF 45/113 reads (40%) | catalogued as rs552619701; called by muse, mutect2, varscan2
- BLM | c.*223C>T | 3'UTR (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- BRWD1 | c.6572-2980C>A | Intron (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- BTK | c.*247G>T | 3'UTR (SNP) | VAF 40/48 reads (83%) | catalogued as COSV100437816; called by muse, mutect2, varscan2
- BX119917.1 | n.9C>T | RNA (SNP) | VAF 47/72 reads (65%) | called by muse, mutect2, varscan2
- C10orf53 | c.*985G>C | 3'UTR (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2
- C11orf80 | c.1043-80C>T | Intron (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- C1R | c.1080+965G>A | Intron (SNP) | VAF 25/74 reads (34%) | catalogued as rs1018684479; called by muse, mutect2, varscan2
- C5orf38 | c.404+29C>T | Intron (SNP) | VAF 47/126 reads (37%) | called by muse, mutect2, varscan2
- CACNA1D | c.4111-42G>A | Intron (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- CACUL1 | c.*1295C>T | 3'UTR (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- CALHM1 | c.*394C>G | 3'UTR (SNP) | VAF 60/205 reads (29%) | called by muse, mutect2, varscan2
- CALHM5 | c.*3442G>A | 3'UTR (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2
- CAMTA2 | c.3262-9C>T | Intron (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- CANT1 | c.*613C>T | 3'UTR (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2
- CASC3 | chr17:40140508 G>A | 5'Flank (SNP) | VAF 58/150 reads (39%) | catalogued as rs762844864, COSV99229878; called by muse, mutect2, varscan2
- CBLN1 | c.-313G>A | 5'UTR (SNP) | VAF 10/34 reads (29%) | called by muse, varscan2
- CCDC117 | c.-35G>A | 5'UTR (SNP) | VAF 22/62 reads (35%) | catalogued as rs959401370; called by muse, mutect2, varscan2
- CCDC138 | c.-41G>A | 5'UTR (SNP) | VAF 25/76 reads (33%) | catalogued as rs1369738676; called by muse, mutect2, varscan2
- CCDC71L | c.*1559C>T | 3'UTR (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- CCDC73 | c.429+126C>G | Intron (SNP) | VAF 44/126 reads (35%) | called by muse, mutect2, varscan2
- CD164 | c.-61G>A | 5'UTR (SNP) | VAF 46/138 reads (33%) | called by muse, mutect2, varscan2
- CD46 | c.1027+70G>A | Intron (SNP) | VAF 11/66 reads (17%) | catalogued as rs1308442813; called by muse, mutect2, varscan2
- CDK13 | c.1211+81C>T | Intron (SNP) | VAF 23/62 reads (37%) | catalogued as rs1248230192; called by muse, mutect2, varscan2
- CDKL4 | chr2:39175881 G>A | 3'Flank (SNP) | VAF 44/78 reads (56%) | catalogued as rs561661705; called by muse, mutect2, varscan2
- CDKN2B | c.*1244G>A | 3'UTR (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- CDS2 | c.*3026C>T | 3'UTR (SNP) | VAF 50/127 reads (39%) | called by muse, mutect2, varscan2
- CDX1 | c.*260C>G | 3'UTR (SNP) | VAF 48/143 reads (34%) | called by muse, mutect2, varscan2
- CEBPB | c.*320G>A | 3'UTR (SNP) | VAF 56/142 reads (39%) | catalogued as COSV100269827; called by muse, mutect2, varscan2
- CEP78 | c.*4402G>C | 3'UTR (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- CERK | c.*2370C>T | 3'UTR (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- CFL2 | c.3+23G>A | Intron (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- CHFR | chr12:132840283 C>T | 3'Flank (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- CHRNA5 | c.*1520T>C | 3'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- CHRNB1 | c.-26G>A | 5'UTR (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- CHST3 | c.*3344T>C | 3'UTR (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
- CLASP2 | c.862+237C>T | Intron (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
- CLEC4G | c.221-35G>A | Intron (SNP) | VAF 18/81 reads (22%) | catalogued as rs1223841681; called by mutect2, varscan2
- CLRN1 | chr3:150926373 C>T | 3'Flank (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- COBLL1 | c.64+25G>A | Intron (SNP) | VAF 26/42 reads (62%) | called by muse, varscan2
- COPS8 | c.*1966G>A | 3'UTR (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- CRCT1 | c.-4C>T | 5'UTR (SNP) | VAF 75/266 reads (28%) | catalogued as COSV57500179; called by muse, mutect2, varscan2
- CRHR2 | c.90+60C>T | Intron (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- CRYBA2 | c.303+78C>G | Intron (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- CSMD1 | c.-298C>T | 5'UTR (SNP) | VAF 9/27 reads (33%) | catalogued as COSV68207843; called by muse, mutect2, varscan2
- CTCF | c.*1073C>A | 3'UTR (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- CTDSP1 | c.-213C>G | 5'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- CTNND2 | c.*1477G>C | 3'UTR (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- CTSD | c.*437C>G | 3'UTR (SNP) | VAF 54/121 reads (45%) | catalogued as rs698450; called by muse, mutect2, varscan2
- CTSS | c.*1119C>T | 3'UTR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- CUL7 | c.-36C>T | 5'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- CXCR3 | c.*271C>T | 3'UTR (SNP) | VAF 33/43 reads (77%) | called by muse, mutect2, varscan2
- DCHS2 | n.1502C>G | RNA (SNP) | VAF 58/152 reads (38%) | called by muse, mutect2, varscan2
- DCT | c.*1436C>G | 3'UTR (SNP) | VAF 17/23 reads (74%) | called by muse, mutect2, varscan2
- DDX27 | c.1367-154C>G | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- DDX39B | c.-3+142C>T | Intron (SNP) | VAF 48/114 reads (42%) | catalogued as rs931986231; called by muse, mutect2, varscan2
- DEPDC5 | c.1666+490C>T | Intron (SNP) | VAF 9/27 reads (33%) | called by muse, varscan2
- DIS3L | c.2201+23G>A | Intron (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- DRAM1 | c.*1878C>T | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- DTX2P1 | n.303C>G | RNA (SNP) | VAF 57/137 reads (42%) | catalogued as rs1372146214; called by muse, mutect2, varscan2
- DUSP5 | c.*857C>T | 3'UTR (SNP) | VAF 41/116 reads (35%) | called by muse, mutect2, varscan2
- ECT2L | c.*447G>A | 3'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2
- EED | c.-414G>A | 5'UTR (SNP) | VAF 67/149 reads (45%) | called by muse, mutect2, varscan2
- EFCAB2 | c.*2349C>T | 3'UTR (SNP) | VAF 61/240 reads (25%) | catalogued as rs1252269326; called by muse, mutect2, varscan2
- EHBP1L1 | c.3093+50G>A | Intron (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- ELK4 | c.1081-219G>A | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- ELOVL6 | c.*1590G>C | 3'UTR (SNP) | VAF 26/80 reads (33%) | called by muse, varscan2
- ENTPD5 | c.*438G>A | 3'UTR (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2, varscan2
- EOLA1 | c.-211+412G>A | Intron (SNP) | VAF 17/25 reads (68%) | catalogued as rs1291044482; called by muse, mutect2, varscan2
- EPAS1 | c.*1308G>C | 3'UTR (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- EPHA10 | c.*2229C>G | 3'UTR (SNP) | VAF 66/182 reads (36%) | called by muse, mutect2, varscan2
- ERCC6 | c.*693C>T | 3'UTR (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+7681G>T | Intron (SNP) | VAF 46/121 reads (38%) | called by muse, mutect2, varscan2
- FAM114A1 | c.*140G>A | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- FAM114A1 | c.*340G>C | 3'UTR (SNP) | VAF 37/92 reads (40%) | called by muse, mutect2, varscan2
- FAM114A1 | c.*877G>A | 3'UTR (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- FAM118A | c.522+392C>T | Intron (SNP) | VAF 21/48 reads (44%) | catalogued as rs757119767; called by muse, mutect2, varscan2
- FAM133B | c.-91G>A | 5'UTR (SNP) | VAF 61/148 reads (41%) | called by muse, mutect2, varscan2
- FAM151B | chr5:80487996 C>T | 5'Flank (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2
- FAM193B | c.210+697C>A | Intron (SNP) | VAF 12/17 reads (71%) | called by muse, mutect2, varscan2
- FAM219A | c.*1613G>C | 3'UTR (SNP) | VAF 57/185 reads (31%) | called by muse, mutect2, varscan2
- FAM76B | c.-44C>T | 5'UTR (SNP) | VAF 20/52 reads (38%) | catalogued as rs774626628; called by muse, mutect2, varscan2
- FBXW7 | c.502-2690G>A | Intron (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2
- FBXW8 | chr12:117029996 G>T | 3'Flank (SNP) | VAF 48/134 reads (36%) | called by muse, mutect2, varscan2
- FCRL1 | c.*1203C>G | 3'UTR (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- FER | c.1924+4137G>T | Intron (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- FOXC1 | c.*957C>A | 3'UTR (SNP) | VAF 49/126 reads (39%) | catalogued as rs1029465164; called by muse, mutect2, varscan2
- FRMD3 | c.*1546G>C | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- FUT2 | chr19:48705684 C>G | 3'Flank (SNP) | VAF 37/98 reads (38%) | called by muse, mutect2, varscan2
- GABRB2 | c.*1949G>A | 3'UTR (SNP) | VAF 30/97 reads (31%) | catalogued as rs1311280506; called by muse, mutect2, varscan2
- GABRG1 | c.*2373C>A | 3'UTR (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- GARRE1 | c.-128C>T | 5'UTR (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- GATM | chr15:45378828 G>A | 5'Flank (SNP) | VAF 28/75 reads (37%) | called by muse, varscan2
- GDF15 | c.277+97C>G | Intron (SNP) | VAF 74/224 reads (33%) | called by mutect2, varscan2
- GIGYF1 | c.*87G>C | 3'UTR (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- GLIPR1 | c.*3529C>T | 3'UTR (SNP) | VAF 55/138 reads (40%) | called by muse, mutect2, varscan2
- GOLGA4 | chr3:37243087 G>A | 5'Flank (SNP) | VAF 28/71 reads (39%) | catalogued as rs1275939269; called by muse, mutect2
- GREM2 | c.*1414C>A | 3'UTR (SNP) | VAF 53/154 reads (34%) | called by muse, mutect2, varscan2
- GRIK3 | c.*4766G>A | 3'UTR (SNP) | VAF 62/157 reads (39%) | called by muse, mutect2, varscan2
- GRIN2A | c.*5009G>A | 3'UTR (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- GRIN2C | chr17:74860533 G>A | 5'Flank (SNP) | VAF 41/97 reads (42%) | catalogued as rs775539387; called by muse, mutect2, varscan2
- GTF2H5 | c.*1538G>C | 3'UTR (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- GXYLT1 | c.*1578G>A | 3'UTR (SNP) | VAF 19/42 reads (45%) | catalogued as COSV55142283; called by muse, mutect2, varscan2
- HADHA | c.*213G>C | 3'UTR (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- HAND1 | c.*421C>G | 3'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- HBG2 | chr11:5254992 G>A | 5'Flank (SNP) | VAF 82/481 reads (17%) | called by muse, varscan2
- HCN1 | c.*1882C>G | 3'UTR (SNP) | VAF 47/143 reads (33%) | called by muse, mutect2, varscan2
- HFE | c.*3298G>C | 3'UTR (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- HFE | c.*3702C>G | 3'UTR (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- HHAT | c.*289G>C | 3'UTR (SNP) | VAF 36/157 reads (23%) | catalogued as rs1033404292; called by muse, mutect2, varscan2
- HLA-DQB1 | c.*227G>A | 3'UTR (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- HOXB3 | chr17:48549787 C>T | 3'Flank (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- HPS4 | c.*369C>T | 3'UTR (SNP) | VAF 11/199 reads (6%) | catalogued as rs886057316; ClinVar: uncertain significance; called by muse, mutect2
- HSF1 | c.1384+12C>T | Intron (SNP) | VAF 36/82 reads (44%) | called by mutect2, varscan2
- HYAL2 | c.-46-526G>A | Intron (SNP) | VAF 53/143 reads (37%) | catalogued as rs940145974; called by muse, mutect2, varscan2
- ICA1L | c.235+23C>G | Intron (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- ID1 | c.*86C>T | 3'UTR (SNP) | VAF 29/75 reads (39%) | catalogued as rs1012250246; called by muse, mutect2, varscan2
- ID2 | c.-100G>A | 5'UTR (SNP) | VAF 43/91 reads (47%) | catalogued as COSV99301046, COSV99301128; called by muse, mutect2, varscan2
- IFFO1 | c.1350+42C>T | Intron (SNP) | VAF 38/67 reads (57%) | catalogued as rs1164118862; called by muse, mutect2, varscan2
- IGSF11 | c.*1536C>T | 3'UTR (SNP) | VAF 47/131 reads (36%) | called by muse, mutect2, varscan2
- IL6ST | c.*4920C>G | 3'UTR (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
- INSYN2A | c.*1731C>A | 3'UTR (SNP) | VAF 57/133 reads (43%) | called by muse, mutect2, varscan2
- ITGA3 | c.*1023C>T | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2
- KAT5 | c.592-62G>A | Intron (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- KCNMB4 | c.*3432G>A | 3'UTR (SNP) | VAF 76/222 reads (34%) | called by muse, mutect2, varscan2
- KCNN3 | c.*443C>G | 3'UTR (SNP) | VAF 47/202 reads (23%) | called by muse, mutect2, varscan2
- KCNV1 | chr8:109974984 C>T | 5'Flank (SNP) | VAF 36/108 reads (33%) | called by muse, mutect2, varscan2
- KIAA1549 | c.*5263G>A | 3'UTR (SNP) | VAF 34/84 reads (40%) | called by muse, mutect2, varscan2
- KIAA1549L | c.*2635C>T | 3'UTR (SNP) | VAF 67/193 reads (35%) | called by muse, mutect2
- KIAA2012 | c.1474+29C>G | Intron (SNP) | VAF 60/159 reads (38%) | catalogued as rs1016056886; called by muse, mutect2, varscan2
- KIF20A | c.*60G>T | 3'UTR (SNP) | VAF 41/129 reads (32%) | called by muse, mutect2, varscan2
- KIF26B | c.*87C>T | 3'UTR (SNP) | VAF 24/63 reads (38%) | catalogued as COSV100831820; called by muse, mutect2, varscan2
- KIF3A | c.*1765G>A | 3'UTR (SNP) | VAF 58/181 reads (32%) | called by muse, mutect2, varscan2
- KLC4 | c.-26+665G>T | Intron (SNP) | VAF 33/97 reads (34%) | called by muse, mutect2
- KLF9 | c.-1100C>T | 5'UTR (SNP) | VAF 61/142 reads (43%) | called by muse, mutect2, varscan2
- KLHDC10 | c.*200C>G | 3'UTR (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- KLHL22 | c.-33-539C>G | Intron (SNP) | VAF 55/163 reads (34%) | called by muse, mutect2, varscan2
- KRAS | c.*2351C>G | 3'UTR (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- KRT14 | c.*110C>T | 3'UTR (SNP) | VAF 46/119 reads (39%) | called by muse, mutect2, varscan2
- KRT15 | chr17:41519878 G>A | 5'Flank (SNP) | VAF 64/140 reads (46%) | called by muse, mutect2, varscan2
- KRT73 | c.*243C>G | 3'UTR (SNP) | VAF 32/88 reads (36%) | called by muse, mutect2, varscan2
- KRTAP17-1 | c.*293G>T | 3'UTR (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- LAMC1 | c.*2165G>A | 3'UTR (SNP) | VAF 37/153 reads (24%) | called by muse, mutect2, varscan2
- LARP1 | c.*465C>T | 3'UTR (SNP) | VAF 96/227 reads (42%) | catalogued as rs1177961859; called by muse, mutect2, varscan2
- LARP6 | c.200+2004G>A | Intron (SNP) | VAF 56/124 reads (45%) | called by muse, mutect2, varscan2
- LDAH | c.*436G>C | 3'UTR (SNP) | VAF 15/51 reads (29%) | catalogued as rs1469207686; called by muse, mutect2, varscan2
- LIPI | c.*66C>T | 3'UTR (SNP) | VAF 73/213 reads (34%) | called by muse, mutect2, varscan2
- LIPT1 | c.-93C>G | 5'UTR (SNP) | VAF 44/127 reads (35%) | catalogued as rs776826901; called by muse, mutect2, varscan2
- LMO1 | chr11:8268695 C>T | 5'Flank (SNP) | VAF 10/30 reads (33%) | catalogued as rs1031308629; called by muse, mutect2, varscan2
- LRATD2 | c.*3237G>A | 3'UTR (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- LRCH4 | c.*982G>A | 3'UTR (SNP) | VAF 67/165 reads (41%) | catalogued as rs928081279; called by muse, mutect2, varscan2
- LRRC28 | c.*754G>C | 3'UTR (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1551+376G>A | Intron (SNP) | VAF 38/96 reads (40%) | called by muse, varscan2
- MALT1 | c.*3130C>T | 3'UTR (SNP) | VAF 31/79 reads (39%) | catalogued as rs1450119255; called by muse, mutect2, varscan2
- MAN1B1 | c.*406G>C | 3'UTR (SNP) | VAF 38/136 reads (28%) | called by muse, mutect2
- MAP2K5 | c.*116G>A | 3'UTR (SNP) | VAF 11/206 reads (5%) | catalogued as rs1371154975; called by muse, mutect2
- MAP4K4 | c.2396+41C>G | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2
- MAPK10 | c.311+134C>T | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- MAPK12 | c.426+43C>A | Intron (SNP) | VAF 40/108 reads (37%) | called by muse, mutect2, varscan2
- MARCHF6 | c.*1369G>C | 3'UTR (SNP) | VAF 12/56 reads (21%) | called by mutect2, varscan2
- MARK2 | c.-414G>A | 5'UTR (SNP) | VAF 61/195 reads (31%) | called by muse, mutect2, varscan2
- MBLAC2 | c.*1039C>A | 3'UTR (SNP) | VAF 54/132 reads (41%) | called by muse, varscan2
- MC4R | c.*112G>C | 3'UTR (SNP) | VAF 50/123 reads (41%) | called by muse, mutect2, varscan2
- MCC | c.-536G>A | 5'UTR (SNP) | VAF 48/119 reads (40%) | catalogued as rs893824697; called by muse, mutect2, varscan2
- MCMDC2 | c.*855G>T | 3'UTR (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- MDM1 | c.*678G>A | 3'UTR (SNP) | VAF 9/24 reads (38%) | catalogued as rs936530539; called by muse, mutect2, varscan2
- MECP2 | c.*8104G>C | 3'UTR (SNP) | VAF 73/93 reads (78%) | called by muse, mutect2, varscan2
- MEMO1 | c.62-19792G>A | Intron (SNP) | VAF 61/159 reads (38%) | called by muse, mutect2, varscan2
- MFAP5 | c.*226C>T | 3'UTR (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- MFSD11 | chr17:76737238 C>G | 5'Flank (SNP) | VAF 16/38 reads (42%) | catalogued as rs1245136006; called by muse, mutect2, varscan2
- MIA2 | c.*800G>A | 3'UTR (SNP) | VAF 48/114 reads (42%) | called by muse, mutect2, varscan2
- MIR365B | n.28G>A | RNA (SNP) | VAF 65/204 reads (32%) | catalogued as rs753933844; called by muse, mutect2, varscan2
- MIR600 | chr9:123111654 G>A | 5'Flank (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- MOB4 | chr2:197515622 C>T | 5'Flank (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- MOGS | c.352+63G>C | Intron (SNP) | VAF 59/154 reads (38%) | called by muse, mutect2, varscan2
- MRPL50 | c.*1097C>T | 3'UTR (SNP) | VAF 100/255 reads (39%) | called by muse, mutect2, varscan2
- MRPS35 | chr12:27710733 C>G | 5'Flank (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- MRS2 | c.*1299G>A | 3'UTR (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- MST1L | n.112G>C | RNA (SNP) | VAF 44/334 reads (13%) | catalogued as rs778106909; called by muse, mutect2, varscan2
- MTHFR | c.*617C>G | 3'UTR (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- MYH16 | n.4025G>A | RNA (SNP) | VAF 41/114 reads (36%) | catalogued as rs999891692; called by muse, mutect2, varscan2
- MYL1 | c.-26T>C | 5'UTR (SNP) | VAF 52/138 reads (38%) | called by muse, mutect2, varscan2
- NAA40 | c.*2077C>T | 3'UTR (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- NAA40 | c.*2563G>A | 3'UTR (SNP) | VAF 11/33 reads (33%) | catalogued as rs940554452; called by muse, mutect2
- NAGK | chr2:71068473 G>A | 5'Flank (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- NAP1L5 | c.-24G>C | 5'UTR (SNP) | VAF 52/127 reads (41%) | catalogued as rs371680899; called by muse, mutect2, varscan2
- NAPA | c.667-48G>A | Intron (SNP) | VAF 32/103 reads (31%) | catalogued as rs1183664654; called by muse, mutect2, varscan2
- NAPSB | n.959C>G | RNA (SNP) | VAF 52/131 reads (40%) | called by muse, mutect2, varscan2
- NAPSB | n.894C>T | RNA (SNP) | VAF 62/134 reads (46%) | called by muse, mutect2, varscan2
- NCAPH2 | c.861+25G>A | Intron (SNP) | VAF 24/65 reads (37%) | called by muse, varscan2
- NDST1 | c.*3736G>A | 3'UTR (SNP) | VAF 58/166 reads (35%) | called by muse, mutect2, varscan2
- NDUFA5 | c.*3533G>T | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- NDUFS3 | c.381+109G>A | Intron (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- NEDD4L | c.49-16445G>A | Intron (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- NF1 | c.7870-9T>G | Intron (SNP) | VAF 37/134 reads (28%) | called by muse, mutect2, varscan2
- NFASC | c.*4095G>A | 3'UTR (SNP) | VAF 49/203 reads (24%) | called by muse, mutect2, varscan2
- NHLH2 | c.*634G>A | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- NKD1 | c.-2G>A | 5'UTR (SNP) | VAF 36/94 reads (38%) | catalogued as rs1173034043; called by muse, mutect2, varscan2
- NME4 | c.*168C>T | 3'UTR (SNP) | VAF 34/118 reads (29%) | catalogued as COSV99556801; called by muse, mutect2, varscan2
- NODAL | c.*254G>A | 3'UTR (SNP) | VAF 55/143 reads (38%) | called by muse, mutect2, varscan2
- NPEPPS | c.-92C>G | 5'UTR (SNP) | VAF 4/13 reads (31%) | catalogued as rs1409396879; called by muse, mutect2, varscan2
- NPR3 | c.*2916C>T | 3'UTR (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99423713; called by muse, mutect2, varscan2
- NRBP2 | c.*1296C>T | 3'UTR (SNP) | VAF 36/95 reads (38%) | catalogued as rs966022251; called by muse, mutect2, varscan2
- NRM | c.*249C>T | 3'UTR (SNP) | VAF 45/147 reads (31%) | called by muse, mutect2, varscan2
- NUDT21 | c.*1824C>T | 3'UTR (SNP) | VAF 40/123 reads (33%) | called by muse, mutect2, varscan2
- NUDT21 | c.*573C>T | 3'UTR (SNP) | VAF 46/116 reads (40%) | called by muse, mutect2, varscan2
- NUP155 | c.3931-48C>G | Intron (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- NXPH3 | c.*3114C>T | 3'UTR (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- OBSCN | c.5138-33G>T | Intron (SNP) | VAF 8/108 reads (7%) | catalogued as rs1325874738; called by muse, mutect2
- OR51E2 | c.*231G>C | 3'UTR (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- OSBPL9 | c.1909-77C>T | Intron (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- PACSIN2 | c.*793C>A | 3'UTR (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- PANK3 | c.*5434A>C | 3'UTR (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- PAX7 | c.*2231C>T | 3'UTR (SNP) | VAF 5/129 reads (4%) | called by muse, mutect2
- PCDH7 | c.-874G>A | 5'UTR (SNP) | VAF 49/141 reads (35%) | called by muse, mutect2, varscan2
- PCDH7 | c.-555G>A | 5'UTR (SNP) | VAF 100/240 reads (42%) | called by muse, varscan2
- PCDHB11 | c.*125C>G | 3'UTR (SNP) | VAF 12/38 reads (32%) | catalogued as rs1306876868; called by muse, mutect2, varscan2
- PDLIM4 | c.670+85C>T | Intron (SNP) | VAF 76/177 reads (43%) | catalogued as rs1017431672, COSV53804263; called by muse, mutect2, varscan2
- PFKFB2 | c.*252C>G | 3'UTR (SNP) | VAF 38/127 reads (30%) | catalogued as rs984961081; called by muse, mutect2, varscan2
- PGM3 | c.*413G>A | 3'UTR (SNP) | VAF 24/86 reads (28%) | called by muse, mutect2, varscan2
- PGM3 | c.*78G>C | 3'UTR (SNP) | VAF 44/122 reads (36%) | called by muse, mutect2, varscan2
- PHF14 | c.*311G>A | 3'UTR (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- PHLDA3 | c.-153G>T | 5'UTR (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- PIGP | c.*134G>C | 3'UTR (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
- PKP3 | c.1449-95C>T | Intron (SNP) | VAF 6/15 reads (40%) | catalogued as rs1392877331; called by muse, mutect2, varscan2
- PLEKHA7 | c.2008-43C>G | Intron (SNP) | VAF 51/155 reads (33%) | called by muse, mutect2, varscan2
- PLPP4 | c.*235G>A | 3'UTR (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- PLPP6 | c.*1007C>T | 3'UTR (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- PLXNB1 | c.*412C>T | 3'UTR (SNP) | VAF 55/151 reads (36%) | called by muse, mutect2, varscan2
- PNMA8A | c.*1164C>G | 3'UTR (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2
- PPIG | c.*925C>T | 3'UTR (SNP) | VAF 28/46 reads (61%) | called by muse, mutect2, varscan2
- PPP2CA | c.*1121C>G | 3'UTR (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- PRSS22 | c.83-124C>T | Intron (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- PRTG | c.*4858G>A | 3'UTR (SNP) | VAF 43/94 reads (46%) | catalogued as rs1054805717; called by muse, mutect2, varscan2
- PRUNE1 | c.*1198C>G | 3'UTR (SNP) | VAF 58/240 reads (24%) | called by muse, varscan2
- PRUNE1 | c.*1318C>T | 3'UTR (SNP) | VAF 22/116 reads (19%) | called by muse, varscan2
- PRUNE2 | c.*265C>G | 3'UTR (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- PSMC5 | c.24+169C>T | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- PTGS1 | c.*507G>C | 3'UTR (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
- PUS1 | c.-383C>T | 5'UTR (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- RARA | c.179-5510C>T | Intron (SNP) | VAF 67/186 reads (36%) | called by muse, mutect2, varscan2
- RASSF6 | c.*987C>G | 3'UTR (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- RASSF6 | c.*572C>T | 3'UTR (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- RAX | c.*1097G>A | 3'UTR (SNP) | VAF 76/190 reads (40%) | called by muse, mutect2, varscan2
- RBBP4 | c.16+196G>A | Intron (SNP) | VAF 8/23 reads (35%) | catalogued as rs996740113, COSV59385556; called by muse, mutect2
- RCOR3 | c.*745G>A | 3'UTR (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- RCSD1 | c.*1055C>G | 3'UTR (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- REXO1 | c.-30C>G | 5'UTR (SNP) | VAF 42/72 reads (58%) | called by muse, mutect2, varscan2
- RGMA | c.15-761G>A | Intron (SNP) | VAF 74/173 reads (43%) | called by muse, mutect2, varscan2
- RGPD1 | chr2:86903878 C>T | 5'Flank (SNP) | VAF 17/84 reads (20%) | catalogued as rs775668723; called by muse, mutect2, varscan2
- RHOT2 | c.*559C>T | 3'UTR (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- RHPN1 | c.*943C>G | 3'UTR (SNP) | VAF 31/94 reads (33%) | called by muse, mutect2, varscan2
- RNASEK | c.195+347G>A | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as rs1037657033; called by muse, mutect2, varscan2
- ROBO4 | c.2435+60C>T | Intron (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
- RPS3 | chr11:75405121 C>T | 3'Flank (SNP) | VAF 15/63 reads (24%) | catalogued as rs912132655; called by muse, mutect2, varscan2
- RRAGD | c.-251G>A | 5'UTR (SNP) | VAF 55/139 reads (40%) | catalogued as rs1314657270; called by muse, mutect2, varscan2
- RTN3 | chr11:63681461 C>T | 5'Flank (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- RXRB | c.1349-70C>T | Intron (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- SAMD5 | c.*1997G>A | 3'UTR (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- SART3 | c.*412G>A | 3'UTR (SNP) | VAF 36/120 reads (30%) | called by muse, mutect2, varscan2
- SAV1 | chr14:50632429 C>T | 3'Flank (SNP) | VAF 20/65 reads (31%) | catalogued as rs1011888583; called by muse, mutect2, varscan2
- SCART1 | c.*161C>G | 3'UTR (SNP) | VAF 46/127 reads (36%) | called by muse, mutect2, varscan2
- SCRN2 | c.1-48C>T | Intron (SNP) | VAF 14/39 reads (36%) | catalogued as rs1302118976; called by muse, mutect2
- SDHA | c.456+133C>G | Intron (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2
- SDR16C5 | chr8:56300969 G>C | 3'Flank (SNP) | VAF 52/138 reads (38%) | called by muse, varscan2
- SEC61A1 | c.-38G>C | 5'UTR (SNP) | VAF 33/94 reads (35%) | catalogued as rs1456002740; called by muse, mutect2, varscan2
- SECISBP2L | c.*1091G>A | 3'UTR (SNP) | VAF 37/125 reads (30%) | called by muse, mutect2, varscan2
- SECISBP2L | c.-63G>A | 5'UTR (SNP) | VAF 49/121 reads (40%) | catalogued as rs1027196542; called by muse, mutect2, varscan2
- SELENOI | chr2:26346108 G>A | 5'Flank (SNP) | VAF 49/129 reads (38%) | catalogued as rs376678544; called by muse, mutect2, varscan2
- SELL | c.*310C>T | 3'UTR (SNP) | VAF 36/126 reads (29%) | called by muse, varscan2
- SEMA4A | c.*510C>T | 3'UTR (SNP) | VAF 74/301 reads (25%) | catalogued as rs946902747; called by muse, mutect2, varscan2
- SH3BP5 | c.-20C>T | 5'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2
- SHISA9 | c.-19G>C | 5'UTR (SNP) | VAF 15/44 reads (34%) | catalogued as rs964671969; called by muse, mutect2, varscan2
- SHMT1 | c.*68G>A | 3'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- SIGLEC6 | c.*493C>T | 3'UTR (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- SIK2 | c.*5223C>G | 3'UTR (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- SIRPB2 | c.860-470C>G | Intron (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- SIX4 | c.*3617G>A | 3'UTR (SNP) | VAF 38/102 reads (37%) | called by muse, mutect2, varscan2
- SIX4 | c.*1539G>C | 3'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- SKIL | c.*426G>A | 3'UTR (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- SLC22A13 | c.*951G>A | 3'UTR (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- SLC22A16 | c.53+147C>T | Intron (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2
- SLC25A26 | c.707+800G>A | Intron (SNP) | VAF 23/305 reads (8%) | called by muse, mutect2
- SLC2A13 | c.1034+308G>A | Intron (SNP) | VAF 43/108 reads (40%) | called by muse, mutect2, varscan2
- SLC35C2 | c.*668C>T | 3'UTR (SNP) | VAF 40/96 reads (42%) | called by muse, mutect2, varscan2
- SLC37A4 | c.984+111C>T | Intron (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- SLC4A8 | c.1248+186C>T | Intron (SNP) | VAF 40/70 reads (57%) | catalogued as rs1402511191; called by muse, mutect2, varscan2
- SMC4 | chr3:160399837 G>A | 5'Flank (SNP) | VAF 75/200 reads (38%) | catalogued as rs868759380; called by muse, mutect2, varscan2
- SMOC2 | c.*480G>A | 3'UTR (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- SNORC | c.74-309C>G | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2
- SOX11 | c.*3833G>A | 3'UTR (SNP) | VAF 26/93 reads (28%) | called by muse, varscan2
- SOX21 | c.*767G>A | 3'UTR (SNP) | VAF 33/53 reads (62%) | called by muse, mutect2, varscan2
- SOX3 | c.*455G>C | 3'UTR (SNP) | VAF 72/97 reads (74%) | called by muse, mutect2, varscan2
- SP1 | c.*4055C>G | 3'UTR (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- SPICE1 | c.*2003C>G | 3'UTR (SNP) | VAF 34/77 reads (44%) | catalogued as rs990697119; called by muse, mutect2, varscan2
- SPN | c.*4300C>T | 3'UTR (SNP) | VAF 20/48 reads (42%) | catalogued as rs1219553310; called by muse, mutect2, varscan2
- SPRED1 | c.*3151C>G | 3'UTR (SNP) | VAF 32/88 reads (36%) | called by muse, mutect2, varscan2
- SRPK1 | c.*1272G>C | 3'UTR (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- SRPX | c.-36G>A | 5'UTR (SNP) | VAF 62/81 reads (77%) | catalogued as rs1279449199; called by muse, mutect2, varscan2
- SRSF5 | c.-82C>T | 5'UTR (SNP) | VAF 12/22 reads (55%) | catalogued as rs764363876, COSV67937067; called by muse, mutect2, varscan2
- SSPOP | n.3957G>A | RNA (SNP) | VAF 33/116 reads (28%) | catalogued as rs372778854; called by muse, mutect2, varscan2
- SSTR4 | c.-22C>T | 5'UTR (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- ST6GAL1 | c.*871G>A | 3'UTR (SNP) | VAF 43/115 reads (37%) | called by muse, varscan2
- ST6GAL1 | c.*1939G>A | 3'UTR (SNP) | VAF 53/144 reads (37%) | called by muse, mutect2, varscan2
- ST6GALNAC4 | c.*254C>T | 3'UTR (SNP) | VAF 46/130 reads (35%) | called by mutect2, varscan2
- STAB1 | c.4761+29C>G | Intron (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2
- STIM1 | c.1474+1243G>C | Intron (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- STON1 | c.*1306C>T | 3'UTR (SNP) | VAF 38/114 reads (33%) | called by muse, mutect2, varscan2
- STX1A | c.209-63G>A | Intron (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- SUSD6 | c.*2595G>A | 3'UTR (SNP) | VAF 38/58 reads (66%) | called by muse, mutect2, varscan2
- SYS1 | c.*1201C>T | 3'UTR (SNP) | VAF 59/138 reads (43%) | catalogued as rs915187214; called by muse, mutect2, varscan2
- SYT10 | c.*1089G>A | 3'UTR (SNP) | VAF 16/35 reads (46%) | catalogued as rs1356490360; called by muse, mutect2, varscan2
- TACC1 | c.162-143C>T | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- TACC3 | c.2062+99G>A | Intron (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2
- TBC1D5 | c.*1691G>C | 3'UTR (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- TBC1D9B | c.*1162C>T | 3'UTR (SNP) | VAF 39/109 reads (36%) | called by muse, mutect2, varscan2
- TCAIM | c.*474C>T | 3'UTR (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- TCTN3 | c.*570C>G | 3'UTR (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2, varscan2
- THY1 | c.37+175G>A | Intron (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- TIGIT | c.*1102C>T | 3'UTR (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- TLCD3A | c.123-146G>A | Intron (SNP) | VAF 7/18 reads (39%) | catalogued as rs775262065; called by muse, varscan2
- TLE3 | c.373-709G>A | Intron (SNP) | VAF 34/76 reads (45%) | called by muse, mutect2, varscan2
- TLK1 | c.639+40G>A | Intron (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- TMBIM4 | c.97+726G>A | Intron (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- TMC3 | c.*1005C>T | 3'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2
- TMEM131 | c.-102C>A | 5'UTR (SNP) | VAF 42/134 reads (31%) | called by muse, mutect2, varscan2
- TMEM138 | c.300+596C>G | Intron (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- TMEM14A | c.*225C>T | 3'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- TMEM154 | c.-13G>A | 5'UTR (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- TMTC3 | c.*1182G>A | 3'UTR (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- TOR1AIP1 | chr1:179882271 G>A | 5'Flank (SNP) | VAF 108/350 reads (31%) | called by muse, varscan2
- TP63 | c.*785G>A | 3'UTR (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2, varscan2
- TRAK1 | c.480+80G>C | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- TRIM24 | c.-30C>T | 5'UTR (SNP) | VAF 12/21 reads (57%) | catalogued as rs745363753; called by muse, varscan2
- TRIM24 | c.364+169C>G | Intron (SNP) | VAF 24/70 reads (34%) | called by muse, varscan2
- TRIM67 | c.*1525G>A | 3'UTR (SNP) | VAF 69/250 reads (28%) | called by muse, mutect2, varscan2
- TSGA13 | c.*188G>A | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- TTBK1 | c.*140G>A | 3'UTR (SNP) | VAF 18/40 reads (45%) | catalogued as rs1345421117; called by muse, varscan2
- TUBA1B | c.4-406G>A | Intron (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- UBE2K | c.-154G>A | 5'UTR (SNP) | VAF 36/120 reads (30%) | catalogued as rs536698416; called by muse, mutect2, varscan2
- UBE3B | c.3016-491C>G | Intron (SNP) | VAF 55/125 reads (44%) | called by muse, mutect2, varscan2
- UBE4A | chr11:118401287 G>A | 3'Flank (SNP) | VAF 73/217 reads (34%) | called by muse, mutect2, varscan2
- UNC5D | c.*3961G>A | 3'UTR (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- UQCRB | c.*4082G>C | 3'UTR (SNP) | VAF 35/109 reads (32%) | called by muse, mutect2, varscan2
- UTP11 | c.*332C>G | 3'UTR (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- VAPA | c.-5C>G | 5'UTR (SNP) | VAF 40/122 reads (33%) | called by muse, varscan2
- VARS1 | c.1887+20G>C | Intron (SNP) | VAF 40/133 reads (30%) | called by muse, mutect2, varscan2
- VPS33A | c.*1025G>C | 3'UTR (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2, varscan2
- VPS36 | c.*1770C>T | 3'UTR (SNP) | VAF 18/33 reads (55%) | catalogued as rs1005683104; called by muse, mutect2, varscan2
- VPS51 | c.*54C>T | 3'UTR (SNP) | VAF 19/64 reads (30%) | catalogued as COSV99659896; called by muse, mutect2, varscan2
- VPS72 | c.271-55C>G | Intron (SNP) | VAF 35/109 reads (32%) | called by muse, mutect2, varscan2
- VWA5A | chr11:124147658 A>C | 3'Flank (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- WDR91 | c.1491-78G>A | Intron (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- WIPI2 | c.-99G>A | 5'UTR (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- WNT9A | c.*1139C>G | 3'UTR (SNP) | VAF 14/73 reads (19%) | called by mutect2, varscan2
- WWC2 | c.*888G>A | 3'UTR (SNP) | VAF 21/70 reads (30%) | catalogued as rs1292117130; called by muse, mutect2, varscan2
- WWP2 | c.*59G>C | 3'UTR (SNP) | VAF 52/140 reads (37%) | catalogued as COSV100598375; called by muse, mutect2, varscan2
- XCL1 | c.*685C>T | 3'UTR (SNP) | VAF 11/165 reads (7%) | called by muse, mutect2
- XPO4 | c.*1887C>T | 3'UTR (SNP) | VAF 37/63 reads (59%) | called by muse, mutect2, varscan2
- YIPF6 | c.*817G>T | 3'UTR (SNP) | VAF 28/41 reads (68%) | called by muse, mutect2, varscan2
- ZBTB38 | chr3:141447318 C>T | 3'Flank (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- ZCWPW1 | c.361+93C>T | Intron (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2
- ZCWPW1 | c.361+91C>T | Intron (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2
- ZEB2 | c.-119G>A | 5'UTR (SNP) | VAF 42/107 reads (39%) | catalogued as rs975939990; called by muse, mutect2, varscan2
- ZFAT | c.2475+94C>T | Intron (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2
- ZFP2 | c.*411G>T | 3'UTR (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- ZIC2 | c.1076-60G>C | Intron (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- ZNF252P | chr8:145004185 G>C | 5'Flank (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- ZNF322 | c.*916G>A | 3'UTR (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- ZNF326 | c.*743G>A | 3'UTR (SNP) | VAF 26/78 reads (33%) | catalogued as rs994022538; called by muse, mutect2, varscan2
- ZNF584 | c.*32G>A | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2
- ZNF594 | c.*1772C>G | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- ZNF615 | c.-255G>A | 5'UTR (SNP) | VAF 96/225 reads (43%) | catalogued as rs1368523263; called by muse, varscan2
- ZNF619 | c.-149C>T | 5'UTR (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- ZNF704 | c.*10760G>C | 3'UTR (SNP) | VAF 31/100 reads (31%) | called by muse, mutect2, varscan2
- ZNF823 | c.-116G>A | 5'UTR (SNP) | VAF 46/132 reads (35%) | called by muse, mutect2, varscan2
